Somatic mutation profile of tumor specimen HCM-CSHL-1264-C25-01A (aliquot HCM-CSHL-1264-C25-01A-11D-A882-36) from HCMI case HCM-CSHL-1264-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Intraductal papillary-mucinous carcinoma, invasive; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 77.5 years (28,315 days).
Specimen HCM-CSHL-1264-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48ee3ea7-6848-48f4-ae70-715c90db1f5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-1264-C25-11A (Solid Tissue Normal), aliquot HCM-CSHL-1264-C25-11A-01D-A882-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae26d4d9-ee7d-45d9-808a-432e70c79979

The open-access MAF lists 62 somatic variants for this specimen: 49 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 12, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 84/435 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 80/457 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: likely pathogenic / drug response; called by muse, mutect2, varscan2
- ARHGAP22 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 80/702 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140701623; called by muse, mutect2, varscan2
- COL4A1 | c.1253C>A p.S418Y | Missense Mutation (SNP) | VAF 63/482 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV65432380; called by muse, mutect2, varscan2
- CR1 | c.3619G>A p.E1207K | Missense Mutation (SNP) | VAF 33/449 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.079); catalogued as rs568448743; called by muse, mutect2
- DISC1 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 25/658 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as rs1445000401; called by muse, mutect2
- GKN3P | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 40/648 reads (6%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1368668848; called by muse, mutect2
- GOLGA6L7 | c.1790G>A p.R597H | Missense Mutation (SNP) | VAF 72/517 reads (14%) | SIFT tolerated (0.42); catalogued as rs558204184; called by muse, mutect2, varscan2
- GOLM2 | c.447G>C p.K149N | Missense Mutation (SNP) | VAF 76/416 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV55463167; called by muse, mutect2, varscan2
- HDAC9 | c.1873C>A p.R625S | Missense Mutation (SNP) | VAF 81/470 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV67766018, COSV67781511; called by muse, mutect2, varscan2
- HORMAD2 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 36/271 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1021489413; called by muse, mutect2, varscan2
- IL10RA | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 151/679 reads (22%) | catalogued as COSV99923305; called by muse, mutect2, varscan2
- LRFN5 | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 69/534 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99983965; called by muse, mutect2, varscan2
- NAV3 | c.4523C>T p.S1508F | Missense Mutation (SNP) | VAF 94/508 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57111419; called by muse, mutect2
- PCDHB9 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 160/993 reads (16%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as COSV53381048; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1963C>A p.L655I | Missense Mutation (SNP) | VAF 38/544 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV100741408; called by muse, mutect2
- SLC9C2 | c.2212C>T p.R738C | Missense Mutation (SNP) | VAF 56/448 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs201611790, COSV62944546; called by muse, mutect2, varscan2
- SNRNP48 | c.157-1G>A p.X53_splice | Splice Site (SNP) | VAF 10/332 reads (3%) | catalogued as rs1418236805; called by muse, mutect2
- SPTB | c.5185C>T p.R1729W | Missense Mutation (SNP) | VAF 63/420 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as rs753928257, COSV67634796; called by muse, mutect2, varscan2
- SYT6 | c.410C>T p.T137M (on ENST00000610222 / NM_001366225.1; = p.T52M on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 145/555 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1474926870; called by muse, mutect2, varscan2
- TAOK3 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 65/419 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs749728105; called by muse, mutect2, varscan2
- TNRC18 | c.3344C>T p.P1115L | Missense Mutation (SNP) | VAF 144/1004 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776220876, COSV68167546; called by muse, mutect2, varscan2
- TTLL10 | c.1000G>A p.A334T (on ENST00000379289 / NM_001130045.2; = p.A261T on NM_153254.3) | Missense Mutation (SNP) | VAF 86/587 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.121); catalogued as rs776052443; called by muse, mutect2, varscan2
- AKR7A2 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 61/463 reads (13%) | called by muse, varscan2
- ANKRD37 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 44/207 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- C4orf54 | c.4424T>C p.L1475P | Missense Mutation (SNP) | VAF 94/477 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- CCDC88C | c.4700T>C p.V1567A | Missense Mutation (SNP) | VAF 67/370 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DCDC1 | c.3028A>T p.N1010Y (on ENST00000597505 / NM_001367979.1; = p.N117Y on NM_020869.3) | Missense Mutation (SNP) | VAF 25/370 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- DNAJC21 | c.1328A>T p.D443V | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- GNPAT | c.1332C>G p.N444K | Missense Mutation (SNP) | VAF 90/948 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2
- HMCN1 | c.10989G>T p.Q3663H | Missense Mutation (SNP) | VAF 20/636 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HMX3 | c.744G>A p.M248I | Missense Mutation (SNP) | VAF 113/590 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- L3MBTL3 | c.1446G>C p.E482D | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- MAP3K21 | c.1069G>C p.A357P | Missense Mutation (SNP) | VAF 84/789 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MFSD6L | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 94/486 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- MUC16 | c.12694T>C p.Y4232H | Missense Mutation (SNP) | VAF 64/784 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.353); called by muse, mutect2
- NLN | c.1455_1458del p.L486* | Frame Shift Del (DEL) | VAF 79/423 reads (19%) | called by mutect2, pindel, varscan2
- OR2M3 | c.936G>T p.E312D | Missense Mutation (SNP) | VAF 47/336 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PARP10 | c.1075C>T p.H359Y | Missense Mutation (SNP) | VAF 69/1074 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2
- PCDHA7 | c.110A>G p.E37G | Missense Mutation (SNP) | VAF 52/773 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHGA12 | c.2672A>G p.Y891C | Missense Mutation (SNP) | VAF 98/578 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDK4 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 16/261 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.353); called by muse, mutect2
- PRAMEF19 | c.294G>C p.W98C | Missense Mutation (SNP) | VAF 36/761 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.303); called by muse, mutect2
- RIMBP3 | c.4066G>A p.D1356N | Missense Mutation (SNP) | VAF 52/1458 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2
- SERPINF1 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 19/564 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- STKLD1 | c.2018G>A p.C673Y | Missense Mutation (SNP) | VAF 88/487 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2
- TRIM46 | c.1589T>A p.V530D | Missense Mutation (SNP) | VAF 297/601 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TUSC3 | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 24/680 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.86); called by muse, mutect2
- ZNF862 | c.1996A>G p.T666A | Missense Mutation (SNP) | VAF 105/623 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CTAGE15 | c.1383A>G p.R461= | Silent (SNP) | VAF 40/328 reads (12%) | called by muse, mutect2, varscan2
- HTR2A | c.651C>T p.D217= | Silent (SNP) | VAF 86/421 reads (20%) | catalogued as rs533066466, COSV66326736; called by muse, mutect2, varscan2
- IQSEC3 | c.1689G>A p.A563= (on ENST00000538872 / NM_001170738.2; = p.A260= on NM_015232.1) | Silent (SNP) | VAF 28/781 reads (4%) | catalogued as rs1555088068; called by muse, mutect2
- KRTAP5-1 | c.303C>T p.S101= | Silent (SNP) | VAF 38/224 reads (17%) | catalogued as rs201124236; called by muse, mutect2
- RHOXF2B | c.240C>T p.G80= | Silent (SNP) | VAF 160/412 reads (39%) | catalogued as rs782238351, COSV101003982; called by muse, mutect2, varscan2
- SLITRK5 | c.501C>T p.V167= | Silent (SNP) | VAF 96/520 reads (18%) | called by muse, mutect2, varscan2
- SPHKAP | c.2571C>T p.S857= | Silent (SNP) | VAF 91/434 reads (21%) | catalogued as rs533054194, COSV60872663; called by muse, mutect2, varscan2
- SUPT16H | c.2877G>A p.E959= | Silent (SNP) | VAF 61/393 reads (16%) | called by muse, mutect2, varscan2
- SUSD4 | c.261C>T p.D87= | Silent (SNP) | VAF 290/894 reads (32%) | catalogued as rs149710544; called by muse, mutect2, varscan2
- USP11 | c.381C>T p.F127= (on ENST00000218348; = p.F84= on NM_001371072.1) | Silent (SNP) | VAF 105/291 reads (36%) | called by muse, mutect2, varscan2
- VASH2 | c.978C>T p.L326= (on ENST00000517399 / NM_001301056.2; = p.L282= on NM_024749.5) | Silent (SNP) | VAF 56/392 reads (14%) | catalogued as rs569261376; called by muse, mutect2, varscan2
- XRRA1 | c.114G>A p.V38= | Silent (SNP) | VAF 38/488 reads (8%) | catalogued as rs1003070000; called by muse, mutect2
- CALN1 | c.*2987G>A | 3'UTR (SNP) | VAF 66/381 reads (17%) | catalogued as rs962716130; called by muse, mutect2, varscan2
